Somatic mutation profile of tumor specimen TCGA-YT-A95G-01A (aliquot TCGA-YT-A95G-01A-11D-A428-09) from TCGA case TCGA-YT-A95G, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 61.7 years (22,541 days).
Specimen TCGA-YT-A95G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a5b36b8-e82b-4245-9df1-36ce8e48cfd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YT-A95G-10A (Blood Derived Normal), aliquot TCGA-YT-A95G-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0894251-2748-448c-84ea-121b77307417

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027524389, COSV55602526; called by muse, mutect2
- DNAH11 | c.5563T>C p.Y1855H | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286421592; called by muse, mutect2
- SOX5 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557463084, COSV58646879, COSV58648253; called by muse, mutect2, varscan2
- COX18 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP1A2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MIPEP | c.1810C>A p.Q604K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RBAK | c.1200T>G p.L400= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- TH | c.1509C>T p.P503= (on ENST00000381178 / NM_199292.3; = p.P472= on NM_000360.4) | Silent (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
